Gene-level copy-number profile of tumor specimen TARGET-10-PARMMV-09A from TARGET case TARGET-10-PARMMV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,322 days).
Specimen TARGET-10-PARMMV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.1b8938a1-30d2-5267-81f6-a7e5bdd62079.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARMMV-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/9344dae0-81d7-47fe-8270-db4625f6942b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 2,452; copy number 2: 57,534; copy number 3: 22; copy number 4: 116.

Homozygous deletions (total copy number 0; autosomes only): 143 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr7:38,253,380–38,335,514, 15 genes: TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:142,349,152–142,786,224, 60 genes: TRBV6-2, TRBV7-2, TRBV8-1, TRBV5-2, TRBV6-4, TRBV7-3, TRBV8-2, TRBV5-3, TRBV9, TRBV10-1, TRBV11-1, TRBV12-1, TRBV10-2, TRBV11-2, TRBV12-2, TRBV6-5, TRBV7-4, TRBV5-4, TRBV6-6, TRBV7-5, TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes (within-gene range 0–2): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr14:22,415,362–22,528,586, 57 genes: AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27, TRAJ26, TRAJ25, TRAJ24, TRAJ23, TRAJ22, TRAJ21, TRAJ20, TRAJ19, TRAJ18, TRAJ17, TRAJ16.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 65. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
